Somatic mutation profile of tumor specimen ALCH-AF1H-TTP1-A (aliquot ALCH-AF1H-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AF1H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.8 years (22,192 days).
Specimen ALCH-AF1H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84220baf-d212-4413-9cda-98a542e67775.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AF1H-NB1-A (Blood Derived Normal), aliquot ALCH-AF1H-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a00ef1f6-f6b0-4998-9689-be7f9331ca76

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 17 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 17, RNA 3, Nonsense Mutation 2, Splice Region 2, 5'UTR 2, Intron 1, Frame Shift Del 1, 5'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 184/669 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 88/364 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 20/195 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691043, CM115637, COSV52672812, COSV52700410; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGMO | c.573A>T p.Q191H | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as rs747881131; called by muse, mutect2, varscan2
- ATG2A | c.1472C>T p.T491M | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as rs143251062; called by muse, mutect2
- CCDC27 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs560903163, COSV53899839; called by muse, mutect2, varscan2
- CEMIP | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs199948256, COSV99585974; called by muse, mutect2
- CNTNAP5 | c.2492A>G p.N831S | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV70483885; called by muse, mutect2, varscan2
- DNAI2 | c.1347+5C>T | Splice Region (SNP) | VAF 21/267 reads (8%) | catalogued as rs557716808; called by muse, mutect2
- DPF1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV62792826, COSV62793491; called by muse, mutect2, varscan2
- DYSF | c.6008G>A p.G2003D | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395588065; ClinVar: uncertain significance; called by muse, mutect2
- FAT4 | c.11446G>A p.G3816R | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58686309; called by muse, mutect2
- GSTM2 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs1247954722; called by muse, varscan2
- KLF5 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66614238; called by muse, mutect2
- LILRB5 | c.1197C>G p.I399M | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV60255045; called by muse, mutect2
- MYO15A | c.8549G>A p.R2850Q | Missense Mutation (SNP) | VAF 18/262 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs568612566; called by muse, mutect2
- OCLN | c.488C>G p.S163C | Missense Mutation (SNP) | VAF 17/535 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1267876764; called by muse, mutect2
- PACSIN1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs758224914, COSV99762837; called by muse, mutect2
- PAPOLG | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 20/265 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV53181463; called by muse, mutect2
- PCDHB3 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50568542; called by muse, mutect2
- PTPN5 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1013944826, COSV62127754; called by muse, mutect2
- RBFOX1 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV100300797; called by muse, mutect2, varscan2
- RYR2 | c.6505G>A p.E2169K | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63664965, COSV63720100; called by muse, mutect2
- SKAP2 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61727681; called by muse, mutect2, varscan2
- SLC25A16 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV56265714; called by muse, mutect2
- STAB1 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs752284290, COSV104396328; called by muse, mutect2
- STXBP3 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV64182088; called by muse, mutect2
- SZT2 | c.5816G>A p.R1939Q (on ENST00000634258 / NM_001365999.1; = p.R1882Q on NM_015284.4) | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs779576338, COSV65171732; ClinVar: uncertain significance; called by muse, mutect2
- TAF4 | c.3154C>T p.R1052* | Nonsense Mutation (SNP) | VAF 12/284 reads (4%) | catalogued as COSV53334463; called by muse, mutect2
- TCF20 | c.4167G>C p.K1389N | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs370868872; called by muse, mutect2
- ARVCF | c.2781+2T>G p.X927_splice | Splice Site (SNP) | VAF 9/210 reads (4%) | called by muse, mutect2
- C1orf198 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CACNG3 | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CBLN4 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 32/542 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.824); called by muse, mutect2
- CHD8 | c.1223C>G p.S408C (on ENST00000646647 / NM_001170629.2; = p.S129C on NM_020920.4) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- CLCN2 | c.2348T>C p.V783A | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, mutect2
- CREB1 | c.678G>C p.Q226H (on ENST00000432329 / NM_134442.5; = p.Q212H on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- DCHS2 | c.782C>A p.A261E | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DDB2 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 31/240 reads (13%) | called by muse, mutect2, varscan2
- DPY19L4 | c.1981G>C p.D661H | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ENOSF1 | c.762G>T p.Q254H (on ENST00000340116 / NM_001354066.2; = p.Q206H on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EYS | c.9125C>T p.A3042V (on ENST00000370621 / NM_001292009.1; = p.A3021V on NM_001142800.2) | Missense Mutation (SNP) | VAF 21/468 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.394); called by muse, mutect2
- KDM6A | c.4162G>C p.D1388H | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KMT2E | c.3525G>C p.K1175N | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- KRT4 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- LAMA1 | c.8074C>A p.P2692T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.144); called by muse, mutect2
- LAMP2 | c.140A>C p.Q47P | Missense Mutation (SNP) | VAF 97/174 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.248); called by muse, varscan2
- MAGEB4 | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTMR2 | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 30/349 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2
- PAXIP1 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); called by muse, mutect2
- PELO | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.09); called by muse, mutect2
- PITPNM1 | c.3622C>T p.L1208F | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.124); called by muse, mutect2
- PLCB1 | c.2975A>G p.Q992R | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM15 | c.2674+3G>C | Splice Region (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- PRKCB | c.1568A>C p.D523A | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RASGRP1 | c.47A>T p.H16L | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SDE2 | c.1255C>G p.L419V | Missense Mutation (SNP) | VAF 24/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETD1A | c.4810C>A p.Q1604K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC26A9 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SLX4 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SOX21 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 23/312 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); called by muse, mutect2
- SPEG | c.9723C>A p.F3241L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SSTR2 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOP2B | c.1448del p.G483Efs*12 (on ENST00000264331 / NM_001330700.2; = p.G478Efs*12 on NM_001068.3) | Frame Shift Del (DEL) | VAF 53/213 reads (25%) | called by mutect2, pindel, varscan2
- TTN | c.13709A>T p.K4570M (on ENST00000591111; = p.K3643M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/221 reads (13%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFDN | c.4554G>T p.R1518= | Silent (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- CALCRL | c.1257G>A p.A419= | Silent (SNP) | VAF 63/354 reads (18%) | catalogued as rs146718835; called by muse, varscan2
- CCT8L2 | c.900C>T p.D300= | Silent (SNP) | VAF 33/294 reads (11%) | catalogued as rs772533950, COSV63462162; called by muse, mutect2, varscan2
- CSMD2 | c.6000G>T p.L2000= | Silent (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- DERL1 | c.42C>T p.I14= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- GEMIN4 | c.2901A>G p.P967= | Silent (SNP) | VAF 9/44 reads (20%) | called by mutect2, varscan2
- KHNYN | c.615A>G p.A205= | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as rs540170795; called by muse, mutect2
- MEIS1 | c.867G>T p.A289= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as COSV99715248; called by muse, mutect2, varscan2
- MUC7 | c.15G>A p.P5= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs765330448, COSV59217571; called by muse, mutect2, varscan2
- NOX4 | c.69C>A p.L23= | Silent (SNP) | VAF 46/255 reads (18%) | called by muse, mutect2, varscan2
- PAQR9 | c.864C>A p.A288= | Silent (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- PLXNA4 | c.1737G>T p.L579= | Silent (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- SFXN3 | c.276G>C p.L92= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- SOX2 | c.288G>A p.R96= | Silent (SNP) | VAF 14/402 reads (3%) | called by muse, mutect2
- TBL1XR1 | c.168T>A p.G56= | Silent (SNP) | VAF 34/355 reads (10%) | catalogued as COSV61789953; called by muse, mutect2
- TBX3 | c.516G>A p.V172= | Silent (SNP) | VAF 119/399 reads (30%) | called by muse, mutect2, varscan2
- ZNF318 | c.3312G>A p.K1104= | Silent (SNP) | VAF 20/160 reads (13%) | called by muse, varscan2
- AC006372.4 | n.189C>T | RNA (SNP) | VAF 14/253 reads (6%) | catalogued as rs1405039585; called by muse, mutect2
- AC114741.1 | n.448A>C | RNA (SNP) | VAF 15/356 reads (4%) | called by muse, mutect2
- FHL1 | c.*310G>A | 3'UTR (SNP) | VAF 14/216 reads (6%) | called by muse, mutect2
- LINC02716 | n.423G>C | RNA (SNP) | VAF 4/41 reads (10%) | called by mutect2, varscan2
- PLEKHB2 | c.424-65642G>T | Intron (SNP) | VAF 38/198 reads (19%) | called by mutect2, varscan2
- PTGES2 | chr9:128129065 A>G | 5'Flank (SNP) | VAF 55/359 reads (15%) | catalogued as rs1003447883; called by muse, mutect2, varscan2
- SLC5A3 | c.-439C>T | 5'UTR (SNP) | VAF 36/193 reads (19%) | called by muse, mutect2, varscan2
- ZFP64 | c.-12C>T | 5'UTR (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
